Somatic mutation profile of tumor specimen TCGA-V1-A8MG-01A (aliquot TCGA-V1-A8MG-01A-11D-A364-08) from TCGA case TCGA-V1-A8MG, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8MG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b48ffe17-4acc-4599-9b57-3a3169efdeaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A8MG-10A (Blood Derived Normal), aliquot TCGA-V1-A8MG-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd6f337d-3f86-4fb7-b824-5f83da7cf823

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.6373C>T p.P2125S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.041); catalogued as COSV101315668; called by muse, mutect2
- CDC7 | c.395T>C p.I132T | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99319632; called by muse, mutect2
- CELSR2 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1216833935, COSV99603366; called by muse, mutect2
- DNAH17 | c.10618C>A p.P3540T | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67749987; called by muse, mutect2
- HAS2 | c.1370C>T p.T457I | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100391565; called by muse, mutect2
- IGSF10 | c.3275C>T p.A1092V | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV99177215; called by muse, mutect2, varscan2
- KDM1A | c.596T>C p.I199T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777578073, COSV100752450; called by mutect2, varscan2
- MYO15A | c.7267G>A p.G2423S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs530783345, COSV52755692, COSV52756702; called by muse, mutect2, varscan2
- PLCXD1 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs372085744, COSV100397679; called by muse, mutect2, varscan2
- PRDM5 | c.1370G>A p.R457K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.237); catalogued as COSV99310140; called by muse, mutect2, varscan2
- TOPORS | c.2681A>G p.K894R | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as COSV100859481; called by muse, mutect2, varscan2
- ZNF558 | c.221A>G p.E74G | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100037882; called by muse, mutect2
- TLR8 | c.335del p.N112Mfs*3 (on ENST00000218032 / NM_138636.5; = p.N130Mfs*3 on NM_016610.4) | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel, varscan2
- APOB | c.2130T>C p.F710= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99264527; called by muse, mutect2, varscan2
- HIVEP3 | c.6750G>A p.S2250= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs139361589; called by mutect2, varscan2
